Somatic mutation profile of tumor specimen HCM-WCMC-1074-C56-01A (aliquot HCM-WCMC-1074-C56-01A-01D-A88H-36) from HCMI case HCM-WCMC-1074-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IC2; Age at diagnosis: 72.9 years (26,625 days).
Specimen HCM-WCMC-1074-C56-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 851bef32-e72b-4689-b16c-a86b43529322.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1074-C56-10A (Blood Derived Normal), aliquot HCM-WCMC-1074-C56-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f91f2f7-9a50-486d-b197-91d35482bc06

The open-access MAF lists 34 somatic variants for this specimen: 20 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 12, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 82/434 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FAM186B | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs766868400; called by muse, mutect2, varscan2
- KEAP1 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50646098; called by muse, mutect2, varscan2
- NPR2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 75/353 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as rs768101143; called by muse, mutect2, varscan2
- PRDM14 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.738); catalogued as rs576020321, COSV52570385, COSV52570815; called by muse, mutect2, varscan2
- SETD5 | c.2416C>A p.Q806K | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.446); catalogued as COSV56712056; called by mutect2, varscan2
- SYT3 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs757705902, COSV58895405, COSV58897241, COSV58898207; called by muse, mutect2
- TAF1L | c.3731G>A p.R1244Q | Missense Mutation (SNP) | VAF 44/417 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs371427336; called by muse, mutect2, varscan2
- ADGRA3 | c.942T>G p.I314M | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CWC27 | c.1116G>T p.K372N | Missense Mutation (SNP) | VAF 21/313 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- DNAH11 | c.8708C>T p.A2903V | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- GPR161 | c.529A>T p.M177L | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- H4C12 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIPK3 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PIEZO2 | c.4234A>T p.I1412F | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RXFP2 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- SYNE1 | c.17458G>A p.E5820K (on ENST00000367255 / NM_182961.4; = p.E5749K on NM_033071.3) | Missense Mutation (SNP) | VAF 19/691 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- TCF24 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF462 | c.3167A>T p.E1056V | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF470 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CFAP47 | c.8031A>T p.V2677= | Silent (SNP) | VAF 28/195 reads (14%) | called by muse, mutect2, varscan2
- COL5A1 | c.4158G>A p.S1386= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as rs1383677988; ClinVar: likely benign; called by muse, varscan2
- IRX1 | c.201G>A p.A67= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as rs767522817, COSV57357712, COSV57363223; called by muse, varscan2
- LRRC8A | c.330C>T p.D110= | Silent (SNP) | VAF 63/274 reads (23%) | catalogued as rs201405629, COSV52189377; called by muse, mutect2, varscan2
- PNPLA3 | c.634C>T p.L212= | Silent (SNP) | VAF 32/196 reads (16%) | catalogued as COSV53377536; called by muse, varscan2
- PRRC2B | c.1203G>A p.R401= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs1161939796; called by muse, mutect2, varscan2
- PXDN | c.1060C>T p.L354= | Silent (SNP) | VAF 47/267 reads (18%) | called by muse, varscan2
- SLCO1B1 | c.366G>A p.R122= | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as rs756788386; called by muse, mutect2, varscan2
- SP3 | c.1893C>G p.V631= | Silent (SNP) | VAF 64/403 reads (16%) | catalogued as COSV59467079; called by muse, mutect2, varscan2
- TBC1D12 | c.567C>G p.S189= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as rs1007911226; called by muse, varscan2
- TPO | c.444G>A p.A148= | Silent (SNP) | VAF 31/259 reads (12%) | catalogued as rs376413622; called by muse, mutect2, varscan2
- TTC30A | c.1951A>C p.R651= | Silent (SNP) | VAF 46/356 reads (13%) | catalogued as rs1335691800; called by muse, mutect2, varscan2
- IGFN1 | c.1241+2580T>C | Intron (SNP) | VAF 58/254 reads (23%) | catalogued as rs1347999943; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-28801T>C | Intron (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2, varscan2
